Somatic mutation profile of tumor specimen MMRF_1583_1_BM_CD138pos (aliquot MMRF_1583_1_BM_CD138pos_T1_KBS5U_L03475) from MMRF case MMRF_1583, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.6 years (18,117 days).
Specimen MMRF_1583_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4654711-d2eb-46d9-9d6d-9fb7d88ac701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1583_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1583_1_PB_CD3pos_C2_KBS5U_L03487; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8102aec-5256-4f5e-8f91-40d25cf6ab47

The open-access MAF lists 30 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, 3'UTR 8, Intron 4, Silent 4, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1395851241; called by muse, mutect2, varscan2
- HOXA5 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV56074242; called by muse, mutect2, varscan2
- PDLIM1 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs199561336, COSV100267665, COSV61473990; called by muse, mutect2, varscan2
- TWIST1 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV54251974; called by muse, mutect2, varscan2
- ARHGAP42 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCNB3 | c.3736A>T p.I1246F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CD40 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH7 | c.293A>C p.D98A | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA11 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK7 | c.814A>T p.S272C | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIEZO2 | c.331T>G p.L111V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); called by mutect2, varscan2
- PPP1R16A | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- R3HCC1L | c.1953T>A p.F651L (on ENST00000612478 / NM_001256619.2; = p.F637L on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSIP2 | c.15573C>T p.V5191= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1456194652; called by muse, mutect2, varscan2
- KMT2A | c.246A>T p.S82= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, varscan2
- PCM1 | c.5718A>G p.L1906= | Silent (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- RAB12 | c.459T>G p.V153= | Silent (SNP) | VAF 49/83 reads (59%) | called by muse, mutect2, varscan2
- GRAMD2A | c.134+321G>T | Intron (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- HESX1 | c.*22A>T | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- KIAA0100 | c.5910+71G>A | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- KLHL3 | c.*2123G>A | 3'UTR (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- MAGIX | chrX:49167419 G>A | 3'Flank (SNP) | VAF 72/141 reads (51%) | catalogued as rs1240655787; called by muse, mutect2, varscan2
- MATN1 | c.442-66C>A | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- MCHR2 | c.*298T>C | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- NFATC2IP | c.*840G>A | 3'UTR (SNP) | VAF 33/67 reads (49%) | catalogued as rs947279862; called by muse, mutect2, varscan2
- OSBP2 | c.1108-5665G>A | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PAM | c.*473A>T | 3'UTR (SNP) | VAF 47/101 reads (47%) | catalogued as rs762403966, COSV57219526; called by muse, mutect2, varscan2
- QSOX1 | c.*3940G>C | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- TYW3 | c.*162G>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- USP51 | c.*1060A>C | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
